Somatic mutation profile of tumor specimen MP2PRT-PARUYH-TMP1-A (aliquot MP2PRT-PARUYH-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARUYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,216 days).
Specimen MP2PRT-PARUYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb81f64f-2c5a-4018-a495-7cbfa130d927.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUYH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUYH-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b27da7eb-87eb-4b4d-8e07-e4784912b90f

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 144/390 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159945, CM150817, COSV56766387, COSV56766702, COSV56766787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHA3 | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); catalogued as COSV60709306; called by muse, mutect2, varscan2
- KCNH2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs201268831, CM124760, CM139883; ClinVar: uncertain significance; called by muse, mutect2
- KIR3DL3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 53/1092 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52545631, COSV99399929; called by muse, mutect2
- RAMAC | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as rs757860183, COSV100417886; called by muse, mutect2, varscan2
- FAM155B | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 36/1039 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.226); called by muse, mutect2
- TEX15 | c.6590C>T p.T2197I (on ENST00000256246; = p.T2580I on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRAF3IP2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 238/610 reads (39%) | called by muse, mutect2, varscan2
- DCBLD1 | c.186C>T p.Y62= | Silent (SNP) | VAF 138/345 reads (40%) | called by muse, mutect2, varscan2
- NDRG2 | c.480G>A p.P160= (on ENST00000298687 / NM_001354570.1; = p.P146= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 115/250 reads (46%) | catalogued as rs775221691; called by muse, varscan2
- SLC6A20 | c.597G>A p.T199= | Silent (SNP) | VAF 185/409 reads (45%) | catalogued as rs556958366; called by muse, varscan2
- SNED1 | c.624C>T p.L208= | Silent (SNP) | VAF 217/554 reads (39%) | catalogued as rs372363359; called by muse, mutect2, varscan2
- CPLANE1 | c.*2367C>T | 3'UTR (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- IGKV3D-20 | chr2:90039479 ins CC | 3'Flank (INS) | VAF 42/90 reads (47%) | called by mutect2, varscan2
